Somatic mutation profile of tumor specimen 0DHV6C from CCDI case PBBULF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 15.4 years (5,632 days).
Specimen 0DHV6C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3676b850-cb3a-4bfe-ac52-26c6e75606e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHV63 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc48d694-773c-484f-bbf4-0fb35fe63c59

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, 5'UTR 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AIF1L | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 33/353 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.776); called by muse, mutect2
- FABP3 | c.*55G>A | 3'UTR (SNP) | VAF 11/228 reads (5%) | called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 20/186 reads (11%) | called by muse, varscan2
